Somatic mutation profile of tumor specimen 0DWTBZ from CCDI case PBCNYT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Lymph nodes of axilla or arm; Age at diagnosis: 18.5 years (6,764 days).
Specimen 0DWTBZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d56fd05-3581-4958-a2cc-af0f88b2cdff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWTA8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e33789cb-6647-4294-a824-d64ea3163341

The open-access MAF lists 28 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 6, Intron 3, 5'UTR 2, Nonsense Mutation 2, Frame Shift Del 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.351G>T p.K117N | Missense Mutation (SNP) | VAF 213/356 reads (60%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV54236714, COSV54237107; called by muse, mutect2, varscan2
- ALB | c.1406G>C p.R469T | Missense Mutation (SNP) | VAF 103/264 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.847); catalogued as COSV55738898; called by muse, mutect2, varscan2
- DPP10 | c.1521C>A p.D507E | Missense Mutation (SNP) | VAF 97/232 reads (42%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV59725145; called by muse, mutect2, varscan2
- HNRNPA1 | c.581del p.R194Kfs*135 (on ENST00000340913 / NM_031157.4; = p.R194Kfs*83 on NM_002136.4) | Frame Shift Del (DEL) | VAF 122/372 reads (33%) | catalogued as COSV52938920; called by mutect2, varscan2
- INSRR | c.866G>T p.R289L | Missense Mutation (SNP) | VAF 81/193 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV63876113; called by muse, mutect2, varscan2
- MDGA2 | c.898G>A p.V300M (on ENST00000399232 / NM_001113498.2; = p.V2M on NM_182830.4) | Missense Mutation (SNP) | VAF 64/212 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.817); catalogued as rs759090236; called by muse, mutect2, varscan2
- PELI3 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 89/186 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.731); catalogued as rs779054380; called by muse, mutect2, varscan2
- RIMS3 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 93/207 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as rs761097260; called by muse, mutect2, varscan2
- CPEB1 | c.1625G>C p.R542P (on ENST00000617958; = p.R477P on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/379 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- EYS | c.4001C>A p.S1334* | Nonsense Mutation (SNP) | VAF 78/180 reads (43%) | called by muse, mutect2, varscan2
- GOLGA6L10 | c.1031G>A p.R344K | Missense Mutation (SNP) | VAF 29/326 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KCNU1 | c.39del p.L14Cfs*20 | Frame Shift Del (DEL) | VAF 40/157 reads (25%) | called by mutect2, varscan2
- KRT12 | c.792G>T p.K264N | Missense Mutation (SNP) | VAF 106/378 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- SLC6A5 | c.621C>A p.Y207* | Nonsense Mutation (SNP) | VAF 75/158 reads (47%) | called by muse, mutect2, varscan2
- WDFY4 | c.5860G>T p.A1954S | Missense Mutation (SNP) | VAF 114/231 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZFYVE9 | c.3127C>A p.L1043M | Missense Mutation (SNP) | VAF 8/217 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.925); called by muse, mutect2
- CD209 | c.1212G>A p.A404= | Silent (SNP) | VAF 36/101 reads (36%) | catalogued as rs373806865; called by muse, mutect2, varscan2
- EPRS1 | c.2784A>C p.V928= | Silent (SNP) | VAF 68/152 reads (45%) | called by muse, varscan2
- INO80 | c.1728G>A p.A576= | Silent (SNP) | VAF 71/281 reads (25%) | catalogued as rs140225630; called by muse, mutect2, varscan2
- OR5H2 | c.471C>A p.G157= | Silent (SNP) | VAF 39/168 reads (23%) | called by muse, mutect2, varscan2
- TLL2 | c.2826G>A p.E942= | Silent (SNP) | VAF 91/197 reads (46%) | called by muse, mutect2, varscan2
- ZBTB45 | c.912T>C p.T304= | Silent (SNP) | VAF 37/110 reads (34%) | called by muse, mutect2, varscan2
- ACAT1 | c.334+66T>C | Intron (SNP) | VAF 4/37 reads (11%) | called by muse, varscan2
- BBS1 | c.1696-97G>T | Intron (SNP) | VAF 8/13 reads (62%) | called by muse, mutect2, varscan2
- IBTK | c.3798-42A>T | Intron (SNP) | VAF 4/35 reads (11%) | called by muse, varscan2
- LDOC1 | c.-82G>T | 5'UTR (SNP) | VAF 4/31 reads (13%) | catalogued as rs1376550978; called by muse, varscan2
- RGS8 | c.-268A>G | 5'UTR (SNP) | VAF 2/10 reads (20%) | called by muse, mutect2
- YME1L1 | c.*61A>T | 3'UTR (SNP) | VAF 44/76 reads (58%) | called by muse, varscan2
